Gene-level copy-number profile of tumor specimen TCGA-AY-A54L-01A from TCGA case TCGA-AY-A54L, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.1 years (27,074 days).
Specimen TCGA-AY-A54L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6a9d7e17-89c3-4a0a-91dc-852f93777b26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AY-A54L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd424f0d-2534-432f-9631-3afa7af04d6e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 565; copy number 3: 1,239; copy number 4: 37,072; copy number 5: 8,200; copy number 6: 7,913; copy number 7: 2,380; copy number 8: 703; copy number 9: 1,075; copy number 10: 550; copy number 11: 24; copy number 13: 6; copy number 14: 12; copy number 15: 28; copy number 22: 53.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AY-A54L-01A-11D-A28F-01): tumor purity 0.44, ploidy 3.65, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,666 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:83,955,777–93,574,730, 112 genes, copy number 10 (broad region; genes not listed).
- chr7:93,669,826–93,670,077, 1 gene, copy number 10: AC002075.2.
- chr7:110,662,644–111,562,517, 1 gene, copy number 10 (within-gene range 8–10): IMMP2L.
- chr7:111,091,006–123,971,414, 164 genes, copy number 9–10 (broad region; genes not listed).
- chr13:24,680,408–28,678,959, 93 genes, copy number 14–22 (broad region; genes not listed).
- chr13:89,991,831–90,231,682, 6 genes, copy number 13: PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622.
- chr20:87,250–21,389,825, 406 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr20:31,303,212–64,313,132, 883 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 565. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
